Somatic mutation profile of cancer-model specimen HCM-SANG-0309-C15-85A (3D Organoid; aliquot HCM-SANG-0309-C15-85A-01D-A78M-36), derived from the primary tumor of HCMI case HCM-SANG-0309-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0309-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 871109ad-5f44-47fe-8759-c9777fa8df6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0309-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0309-C15-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11f8a343-c1b9-40c2-8e16-55ad357c20ef

The open-access MAF lists 178 somatic variants for this specimen: 121 protein-altering or splice-affecting, 34 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 34, Intron 11, Nonsense Mutation 7, RNA 5, Frame Shift Del 5, 3'UTR 3, In Frame Del 3, 5'UTR 3, Splice Region 2, Splice Site 2, In Frame Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 390/391 reads (100%) | hotspot (GDC flag); catalogued as rs730882001, COSV52677910, COSV52844585, COSV53637782; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1595C>T p.S532L | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs1273673749, COSV52814865; called by muse, mutect2, varscan2
- AJM1 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 384/589 reads (65%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); catalogued as rs746713977; called by muse, mutect2, varscan2
- ARC | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1295390020; called by muse, mutect2
- ARHGEF11 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 24/622 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV63813817; called by muse, mutect2
- ARMCX5-GPRASP2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.748); catalogued as COSV63437365; called by muse, mutect2, varscan2
- ASTN1 | c.2269G>A p.G757S | Missense Mutation (SNP) | VAF 190/244 reads (78%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV56071993; called by muse, mutect2, varscan2
- CNTNAP4 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145844553; called by muse, mutect2, varscan2
- CNTNAP4 | c.1958A>G p.Y653C | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs1303417472; called by muse, mutect2
- COQ6 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 164/414 reads (40%) | catalogued as rs376848848; called by muse, mutect2, varscan2
- DCLK1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55203404; called by muse, mutect2, varscan2
- EP400 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as rs762680481, COSV57782537; called by muse, mutect2, varscan2
- F13A1 | c.2082A>C p.E694D | Missense Mutation (SNP) | VAF 233/356 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV53555871; called by muse, mutect2, varscan2
- FAM135B | c.1661T>C p.I554T | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs374654603; called by muse, mutect2, varscan2
- GAD2 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs779103489; called by muse, mutect2, varscan2
- GNAS | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 129/505 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs777891316, COSV58348038; called by muse, mutect2, varscan2
- GRM4 | c.1844C>T p.T615M | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780360848, COSV100945646; called by muse, mutect2, varscan2
- GSAP | c.2474-5dup | Splice Region (INS) | VAF 28/100 reads (28%) | catalogued as rs757049881; called by mutect2, varscan2
- GSDMA | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 210/1855 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.207); catalogued as rs1271993391, COSV52860107; called by muse, mutect2, varscan2
- HSP90B1 | c.2017A>G p.I673V | Missense Mutation (SNP) | VAF 132/132 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs760451741; called by muse, mutect2, varscan2
- KCNH3 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 120/276 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs765393870, COSV57791164; called by muse, mutect2, varscan2
- KCNQ3 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 226/453 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267601778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA5 | c.2629G>T p.E877* | Nonsense Mutation (SNP) | VAF 27/315 reads (9%) | catalogued as rs1294285678; called by muse, mutect2
- LRCH3 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 130/205 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58390108; called by muse, mutect2, varscan2
- MAP2 | c.4898A>G p.K1633R | Missense Mutation (SNP) | VAF 241/243 reads (99%) | SIFT tolerated (0.2); PolyPhen benign (0.287); catalogued as COSV52304258; called by muse, mutect2, varscan2
- MMP28 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 184/185 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs371940194; called by muse, mutect2, varscan2
- MYCN | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 151/866 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558536389, COSV55261260; called by muse, mutect2, varscan2
- MYH8 | c.4319C>T p.A1440V | Missense Mutation (SNP) | VAF 248/594 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as rs754482819; called by muse, mutect2, varscan2
- NELL2 | c.331C>G p.H111D | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV61584319; called by muse, mutect2, varscan2
- OR10A5 | c.781T>G p.F261V | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV55055216; called by muse, mutect2, varscan2
- OR52N1 | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.028); catalogued as COSV57692824; called by muse, mutect2, varscan2
- PABPN1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 156/685 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs758290474, COSV99391082; called by muse, mutect2, varscan2
- PAPPA2 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 92/372 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345464935, COSV62772065, COSV62772735; called by muse, mutect2, varscan2
- PCDHGB3 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 142/341 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53921139; called by muse, mutect2, varscan2
- PPP3CB | c.562A>T p.M188L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.362); catalogued as rs753897852, COSV61153389; called by muse, mutect2, varscan2
- PRDM2 | c.2714A>G p.N905S | Missense Mutation (SNP) | VAF 52/372 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV52454763; called by muse, mutect2, varscan2
- PREX1 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 127/262 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766440280; called by muse, mutect2, varscan2
- PTCH1 | c.655-1G>T p.X219_splice | Splice Site (SNP) | VAF 19/449 reads (4%) | catalogued as COSV59499887; called by muse, mutect2
- RASA4 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 151/966 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1477131131; called by muse, mutect2, varscan2
- RBM42 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs754225112, COSV52897736; called by muse, mutect2, varscan2
- SDCCAG8 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.231); catalogued as COSV59405658; called by muse, mutect2, varscan2
- SETDB2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs200801016; called by muse, varscan2
- SLCO1B1 | c.1193A>C p.K398T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57007790; called by muse, mutect2, varscan2
- SLK | c.10_12del p.F4del | In Frame Del (DEL) | VAF 29/58 reads (50%) | catalogued as rs779771559; called by pindel, varscan2
- SMOC2 | c.794C>T p.T265M (on ENST00000356284 / NM_001166412.2; = p.T276M on NM_022138.3) | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777443867; called by muse, mutect2, varscan2
- SPEF2 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV56801130; called by muse, varscan2
- SPG11 | c.6887A>C p.K2296T | Missense Mutation (SNP) | VAF 160/488 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs889145962; called by muse, mutect2, varscan2
- SPNS1 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs762210057; called by muse, mutect2, varscan2
- STXBP1 | c.1256C>T p.T419M | Missense Mutation (SNP) | VAF 171/523 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs748965227, COSV64813344; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SYT11 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 74/319 reads (23%) | catalogued as rs374290876; called by muse, mutect2, varscan2
- SYT7 | c.1079A>G p.K360R | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201342343; called by muse, mutect2, varscan2
- TAT | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 206/796 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs747367241, COSV63533120; called by muse, mutect2, varscan2
- TCTE1 | c.100A>C p.S34R | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV65256168; called by muse, mutect2, varscan2
- TMPRSS11F | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs542655796, COSV62464715; called by muse, mutect2, varscan2
- TRIM22 | c.304A>C p.K102Q | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV66091803; called by muse, mutect2, varscan2
- WDFY4 | c.9056G>A p.R3019H | Missense Mutation (SNP) | VAF 107/219 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs969942181; called by muse, mutect2, varscan2
- ZNF836 | c.354C>A p.N118K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs1568570455; called by muse, mutect2, varscan2
- AC104389.6 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ADAMTSL1 | c.2072del p.V691Afs*11 | Frame Shift Del (DEL) | VAF 127/401 reads (32%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- AHNAK2 | c.11389_11392del p.T3797Pfs*40 | Frame Shift Del (DEL) | VAF 101/467 reads (22%) | called by mutect2, pindel, varscan2
- AJAP1 | c.1003T>G p.F335V | Missense Mutation (SNP) | VAF 21/707 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AMER3 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 110/110 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ARSK | c.1150T>A p.L384I | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- C2CD4B | c.847_852dup p.R283_A284dup | In Frame Ins (INS) | VAF 88/332 reads (27%) | called by mutect2, varscan2
- CCDC146 | c.1768A>C p.K590Q | Missense Mutation (SNP) | VAF 127/190 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CCDC34 | c.443_448dup p.F149_I150insRF | In Frame Ins (INS) | VAF 59/253 reads (23%) | called by mutect2, pindel, varscan2
- CEBPD | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHADL | c.101C>A p.P34Q | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CMYA5 | c.9995C>T p.A3332V | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTN2 | c.1267C>A p.P423T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- COL21A1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 29/92 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CR2 | c.826T>G p.C276G | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP7B1 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 176/363 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- DDX28 | c.999T>G p.F333L | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- DLG1 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DMD | c.1876G>T p.D626Y | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DNAH9 | c.5775T>G p.N1925K | Missense Mutation (SNP) | VAF 74/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DPYSL3 | c.1275C>G p.H425Q | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- F2 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 145/327 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- FBXO46 | c.741dup p.K248Qfs*60 | Frame Shift Ins (INS) | VAF 39/194 reads (20%) | called by mutect2, pindel, varscan2
- FLG | c.538T>C p.S180P | Missense Mutation (SNP) | VAF 118/536 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- GNL1 | c.650G>C p.G217A | Missense Mutation (SNP) | VAF 132/432 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GOLGA6L2 | c.243A>C p.E81D | Missense Mutation (SNP) | VAF 164/362 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HCN1 | c.1733T>A p.M578K | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2
- HIP1 | c.465+1G>A p.X155_splice | Splice Site (SNP) | VAF 177/375 reads (47%) | called by muse, mutect2, varscan2
- IVL | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 107/569 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- KANSL1L | c.2070_2084del p.C692_I696del | In Frame Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- KCNB2 | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 133/268 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- KIAA1217 | c.2646G>T p.M882I | Missense Mutation (SNP) | VAF 195/563 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LPA | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 161/434 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP5 | c.3259C>A p.Q1087K | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MINDY2 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 252/490 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO18A | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 136/206 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- NDRG1 | c.960G>T p.M320I | Missense Mutation (SNP) | VAF 94/566 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- NPHS1 | c.2536del p.L846* | Frame Shift Del (DEL) | VAF 264/813 reads (32%) | called by mutect2, pindel, varscan2
- NUP210 | c.5510T>G p.L1837R | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP43 | c.227_234del p.D76Gfs*6 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- PCDHB3 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLOD1 | c.171G>A p.A57= | Splice Region (SNP) | VAF 186/368 reads (51%) | called by muse, mutect2, varscan2
- POLR1C | c.899C>G p.A300G | Missense Mutation (SNP) | VAF 142/511 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRG2 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 138/624 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- PRRT4 | c.2507C>T p.P836L | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.055); called by muse, mutect2
- RADIL | c.1840T>G p.S614A | Missense Mutation (SNP) | VAF 432/601 reads (72%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RSPH6A | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 230/522 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- RUSC2 | c.1327T>G p.S443A | Missense Mutation (SNP) | VAF 171/499 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SENP7 | c.2835_2842del p.V946Hfs*16 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- SETBP1 | c.2058C>A p.S686R | Missense Mutation (SNP) | VAF 14/494 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2
- SPATC1 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- TMEM200C | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 340/689 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM67 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 136/648 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMPRSS9 | c.2968T>C p.S990P (on ENST00000648592; = p.S956P on NM_182973.2) | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRBV20-1 | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 63/245 reads (26%) | called by muse, mutect2, varscan2
- TSHZ3 | c.1413G>C p.K471N | Missense Mutation (SNP) | VAF 18/592 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2
- TTC21A | c.2545A>G p.S849G | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- USP48 | c.2585C>A p.A862D | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZBTB4 | c.2876G>T p.G959V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ZC3H7B | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 135/274 reads (49%) | called by muse, mutect2, varscan2
- ZIM3 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 105/459 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ZNF420 | c.1430G>T p.C477F | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF850 | c.3194_3197delinsT p.Y1065_E1066delinsL | In Frame Del (DEL) | VAF 58/346 reads (17%) | called by pindel, varscan2*
- ARSK | c.1149G>C p.P383= | Silent (SNP) | VAF 46/132 reads (35%) | called by muse, mutect2, varscan2
- BMP1 | c.2751C>T p.C917= | Silent (SNP) | VAF 109/216 reads (50%) | catalogued as rs376975956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNC1 | c.873T>G p.T291= | Silent (SNP) | VAF 87/222 reads (39%) | catalogued as COSV100596944, COSV100597241; called by muse, mutect2, varscan2
- CHST9 | c.1059C>T p.V353= | Silent (SNP) | VAF 31/265 reads (12%) | called by muse, mutect2, varscan2
- CUBN | c.3180T>G p.T1060= | Silent (SNP) | VAF 81/231 reads (35%) | catalogued as COSV64715156; called by muse, mutect2, varscan2
- DENND4B | c.705C>T p.V235= | Silent (SNP) | VAF 109/422 reads (26%) | called by muse, mutect2, varscan2
- DNAH9 | c.3828T>G p.S1276= | Silent (SNP) | VAF 129/268 reads (48%) | called by muse, mutect2, varscan2
- GAS7 | c.51C>T p.H17= | Silent (SNP) | VAF 109/455 reads (24%) | catalogued as rs752069937; called by muse, mutect2, varscan2
- GLP2R | c.369T>G p.P123= | Silent (SNP) | VAF 58/276 reads (21%) | called by muse, mutect2, varscan2
- GPR179 | c.555G>A p.E185= | Silent (SNP) | VAF 59/203 reads (29%) | called by muse, mutect2, varscan2
- IGKV1D-16 | c.21T>A p.A7= | Silent (SNP) | VAF 189/543 reads (35%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.1254C>T p.H418= | Silent (SNP) | VAF 45/321 reads (14%) | catalogued as rs746606444; called by muse, mutect2, varscan2
- MACF1 | c.6216A>G p.V2072= | Silent (SNP) | VAF 59/115 reads (51%) | called by muse, mutect2, varscan2
- MANEAL | c.54C>T p.F18= | Silent (SNP) | VAF 58/108 reads (54%) | catalogued as rs1368221781; called by muse, mutect2, varscan2
- MFNG | c.477C>T p.F159= | Silent (SNP) | VAF 36/108 reads (33%) | called by muse, varscan2
- MFNG | c.414C>T p.F138= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as rs1044276282; called by muse, varscan2
- MKRN2OS | c.189C>A p.L63= | Silent (SNP) | VAF 58/103 reads (56%) | called by muse, mutect2, varscan2
- MREG | c.313A>C p.R105= | Silent (SNP) | VAF 110/110 reads (100%) | called by muse, mutect2, varscan2
- MUC19 | c.873G>A p.A291= | Silent (SNP) | VAF 93/94 reads (99%) | catalogued as rs747068521; called by muse, mutect2, varscan2
- MYH8 | c.4320A>G p.A1440= | Silent (SNP) | VAF 249/599 reads (42%) | called by muse, mutect2, varscan2
- NAP1L2 | c.639A>G p.E213= | Silent (SNP) | VAF 75/79 reads (95%) | catalogued as COSV65172720; called by muse, mutect2, varscan2
- NBPF14 | c.7971A>G p.E2657= | Silent (SNP) | VAF 92/672 reads (14%) | called by muse, mutect2, varscan2
- NMT2 | c.127T>C p.L43= | Silent (SNP) | VAF 34/194 reads (18%) | called by muse, mutect2, varscan2
- NPNT | c.1416C>T p.L472= | Silent (SNP) | VAF 98/189 reads (52%) | catalogued as rs772721145, COSV99975045; called by muse, mutect2, varscan2
- OGDHL | c.855C>T p.S285= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as rs774693788, COSV65100776; called by muse, mutect2, varscan2
- PI16 | c.699T>A p.P233= | Silent (SNP) | VAF 73/334 reads (22%) | called by muse, mutect2, varscan2
- PLXNB3 | c.4551G>A p.T1517= | Silent (SNP) | VAF 215/215 reads (100%) | catalogued as rs782694231; called by muse, mutect2, varscan2
- PRKCZ | c.396C>T p.L132= | Silent (SNP) | VAF 92/276 reads (33%) | catalogued as rs1275420894, COSV101057669; called by muse, mutect2, varscan2
- RICTOR | c.18C>T p.R6= | Silent (SNP) | VAF 216/306 reads (71%) | catalogued as rs1460198401; called by muse, mutect2, varscan2
- RTP5 | c.1209C>T p.D403= | Silent (SNP) | VAF 54/54 reads (100%) | catalogued as rs775719201; called by muse, mutect2, varscan2
- TIAM1 | c.1440C>T p.D480= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as rs745535556, COSV54545301; called by muse, mutect2, varscan2
- TMEM184A | c.1182C>T p.G394= | Silent (SNP) | VAF 69/259 reads (27%) | catalogued as rs778970084; called by muse, mutect2, varscan2
- TRPC3 | c.1458G>A p.T486= (on ENST00000379645 / NM_001366479.2; = p.T413= on NM_003305.2) | Silent (SNP) | VAF 13/211 reads (6%) | catalogued as rs41278089; called by muse, mutect2
- VRK1 | c.603T>C p.A201= | Silent (SNP) | VAF 106/271 reads (39%) | catalogued as rs1157448476; called by muse, mutect2, varscan2
- AL136982.4 | n.1577G>A | RNA (SNP) | VAF 172/495 reads (35%) | catalogued as rs745897618; called by muse, mutect2, varscan2
- ANKRD30B | c.2313+110A>G | Intron (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- AREL1 | c.482-1473G>A | Intron (SNP) | VAF 38/264 reads (14%) | called by muse, mutect2, varscan2
- CACNG1 | c.-2C>T | 5'UTR (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- CFAP69 | c.1656+34C>G | Intron (SNP) | VAF 79/137 reads (58%) | called by muse, mutect2, varscan2
- CHIT1 | c.*518A>G | 3'UTR (SNP) | VAF 201/443 reads (45%) | catalogued as rs1294269221; called by muse, mutect2, varscan2
- CICP28 | chr7:56812095 C>A | 3'Flank (SNP) | VAF 170/261 reads (65%) | called by muse, mutect2, varscan2
- FGFR1 | c.1081+38C>T | Intron (SNP) | VAF 99/184 reads (54%) | catalogued as rs750355745, COSV100249684; called by muse, mutect2, varscan2
- GRIA4 | c.2544+58G>A | Intron (SNP) | VAF 68/218 reads (31%) | called by muse, mutect2, varscan2
- GUSBP10 | n.89C>A | RNA (SNP) | VAF 48/248 reads (19%) | called by muse, mutect2, varscan2
- KLK12 | c.*156A>T | 3'UTR (SNP) | VAF 177/831 reads (21%) | called by muse, mutect2, varscan2
- MGAM | c.4618+12927A>G | Intron (SNP) | VAF 61/131 reads (47%) | called by muse, mutect2, varscan2
- MGLL | c.481-5040G>A | Intron (SNP) | VAF 196/301 reads (65%) | called by muse, mutect2, varscan2
- MIR512-2 | n.64G>C | RNA (SNP) | VAF 41/227 reads (18%) | called by muse, mutect2, varscan2
- MYADML | n.1075C>T | RNA (SNP) | VAF 139/539 reads (26%) | catalogued as rs1481074077; called by muse, mutect2, varscan2
- PAK1 | c.1552-1986A>C | Intron (SNP) | VAF 28/384 reads (7%) | called by muse, mutect2
- RNF213 | c.3024+167_3024+168dup | Intron (INS) | VAF 168/345 reads (49%) | called by mutect2, pindel, varscan2
- RPS27A | c.321+51_321+63del | Intron (DEL) | VAF 138/307 reads (45%) | called by mutect2, pindel, varscan2
- SIX4 | c.-207A>C | 5'UTR (SNP) | VAF 63/220 reads (29%) | catalogued as rs940391234; called by muse, mutect2, varscan2
- SLC4A2 | c.51+579_51+581del | Intron (DEL) | VAF 18/69 reads (26%) | catalogued as rs761063738; called by mutect2, pindel, varscan2
- SULF1 | c.*120A>T | 3'UTR (SNP) | VAF 63/239 reads (26%) | called by muse, mutect2, varscan2
- UBTFL2 | n.88C>G | RNA (SNP) | VAF 38/153 reads (25%) | called by muse, mutect2, varscan2
- ZNF451 | c.-29G>A | 5'UTR (SNP) | VAF 51/189 reads (27%) | catalogued as rs1562581482; called by muse, mutect2, varscan2
